Gene-level copy-number profile of tumor specimen C3N-01892-09 from CPTAC case C3N-01892, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 77.6 years (28,359 days).
Specimen C3N-01892-09: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b607758b-fa57-49c7-b3d0-aafe6b07c4cd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01892-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/cdf548c0-0254-4f1d-844b-a3bb9ef5aaf0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 537; copy number 1: 252; copy number 2: 12,474; copy number 3: 3,209; copy number 4: 32,194; copy number 5: 1,987; copy number 6: 5,290; copy number 7: 718; copy number 8: 1,490; copy number 9: 239; copy number 10: 13; copy number 11: 45; copy number 12: 65; copy number 13: 140; copy number 15: 115; copy number 17: 5; copy number 23: 51; copy number 29: 44; copy number 31: 43.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr16:32,388,135–32,460,362, 4 genes: AC138915.2, PABPC1P13, AC138915.3, AC138915.1.
- chr16:32,618,733–32,678,831, 7 genes: AC137800.2, AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3.
- chr16:33,687,025–33,707,213, 1 gene: BMS1P8.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 760 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,739,506, 10 genes, copy number 9–11: AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2.
- chr1:143,811,359–143,825,837, 1 gene, copy number 10: AC239798.1.
- chr1:248,548,756–248,645,278, 9 genes, copy number 12–15: AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr3:82,806,515–82,808,021, 1 gene, copy number 17: CYP51A1P1.
- chr3:180,161,886–181,836,880, 22 genes, copy number 10–17 (within-gene range 5–17): RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1, LINC02053, U8, AC125618.1, RNU6-486P, AC068298.1, TTC14, CCDC39, CCDC39, CCDC39-AS1, AC108734.4, RN7SL229P, AC108734.3, AC108734.2, FLYWCH1P1, FXR1, AC108734.1, DNAJC19, SOX2-OT.
- chr3:181,231,737–184,712,064, 93 genes, copy number 9–15 (broad region; genes not listed).
- chr8:124,823,702–142,917,843, 228 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr13:102,685,744–102,904,000, 12 genes, copy number 11: METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2.
- chr18:721,588–2,489,426, 25 genes, copy number 11: YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3.
- chr22:20,350,578–26,031,045, 359 genes, copy number 9–31 (within-gene range 6–31) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 244. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
